Somatic mutation profile of tumor specimen TCGA-BP-5202-01A (aliquot TCGA-BP-5202-01A-02D-1429-08) from TCGA case TCGA-BP-5202, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.4 years (27,556 days).
Specimen TCGA-BP-5202-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48a41d84-6087-45fa-ab2c-34e1d71be00d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5202-11A (Solid Tissue Normal), aliquot TCGA-BP-5202-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/667d754b-7838-4dd4-b863-58c1d805825f

The open-access MAF lists 38 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACA | c.2867A>G p.K956R | Missense Mutation (SNP) | VAF 120/363 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs760725326; called by muse, mutect2, varscan2
- ACAP1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV50138244; called by muse, mutect2, varscan2
- ACTRT2 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs761400271, COSV65759846, COSV65760527; called by muse, mutect2
- ASTN2 | c.682T>C p.Y228H | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57797769; called by muse, mutect2, varscan2
- BTG2 | c.396T>A p.C132* | Nonsense Mutation (SNP) | VAF 52/161 reads (32%) | catalogued as COSV51856893; called by muse, mutect2, varscan2
- CAND1 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1259301877, COSV73389704; called by muse, mutect2, varscan2
- CATSPER4 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV58793896; called by muse, mutect2, varscan2
- CCDC87 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as COSV59579782; called by muse, mutect2, varscan2
- COL6A6 | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV62031119; called by muse, mutect2
- CSPP1 | c.3578-2A>G p.X1193_splice (on ENST00000676605; = p.X1152_splice on NM_024790.6) | Splice Site (SNP) | VAF 167/564 reads (30%) | catalogued as COSV51588399; called by muse, mutect2, varscan2
- CYP19A1 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs755257022, COSV53060894; called by muse, mutect2, varscan2
- FBXO2 | c.546T>G p.I182M | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV52354817; called by muse, mutect2, varscan2
- FOXRED2 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as rs760554934, COSV53400902; called by muse, mutect2, varscan2
- GABRG1 | c.1139C>A p.P380H | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.617); catalogued as COSV54958083; called by muse, mutect2, varscan2
- HDAC10 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs1210758647, COSV50561549; called by muse, mutect2, varscan2
- HRNR | c.8282G>T p.R2761L | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV64260473; called by muse, mutect2, varscan2
- KRI1 | c.1549G>C p.D517H | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV57265300; called by muse, mutect2, varscan2
- LAMB1 | c.5288G>C p.R1763T | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV52738892; called by muse, varscan2
- MARS1 | c.2182A>G p.I728V | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV56257036; called by muse, mutect2, varscan2
- MUC16 | c.18227C>T p.P6076L | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.686); catalogued as COSV67479693; called by muse, mutect2, varscan2
- NPNT | c.239_241del p.G80_Y81delinsD | In Frame Del (DEL) | VAF 30/93 reads (32%) | catalogued as COSV59755518; called by mutect2, pindel, varscan2
- OR13C5 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66165006; called by muse, mutect2, varscan2
- PLEKHG3 | c.1676G>A p.R559Q (on ENST00000394691; = p.R615Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs750439742, COSV55981704; called by muse, mutect2, varscan2
- RP1L1 | c.1195G>A p.G399R | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0.014); catalogued as rs374843101, COSV66752859; called by muse, mutect2, varscan2
- SCGB2A1 | c.267G>C p.W89C | Missense Mutation (SNP) | VAF 17/308 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.8); catalogued as COSV55276554, COSV99793726; called by muse, mutect2
- SRL | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315293209, COSV68423930; called by muse, mutect2, varscan2
- STIMATE | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV61891242; called by muse, mutect2
- TRMT44 | c.1523A>G p.Y508C | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67663478; called by muse, mutect2, varscan2
- USP16 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV57626721; called by muse, mutect2, varscan2
- ZNF276 | c.1060G>C p.D354H (on ENST00000443381 / NM_001113525.2; = p.D279H on NM_152287.4) | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV57070615; called by muse, varscan2
- KDM5C | c.80del p.P27Lfs*46 | Frame Shift Del (DEL) | VAF 29/50 reads (58%) | called by mutect2, pindel, varscan2
- NIT1 | c.521_534del p.P174Qfs*10 | Frame Shift Del (DEL) | VAF 43/147 reads (29%) | called by mutect2, pindel, varscan2
- BIN2 | c.273C>T p.S91= | Silent (SNP) | VAF 154/469 reads (33%) | catalogued as rs750169427, COSV57203572; called by muse, mutect2, varscan2
- DNAJC30 | c.90C>T p.S30= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as rs369098122; called by muse, mutect2, varscan2
- IGF1R | c.3393C>T p.F1131= | Silent (SNP) | VAF 31/270 reads (11%) | catalogued as rs1022844692, COSV51288638; called by muse, mutect2, varscan2
- RCOR3 | c.1077T>A p.T359= | Silent (SNP) | VAF 66/178 reads (37%) | catalogued as COSV65366292; called by muse, mutect2, varscan2
- SYTL3 | c.771A>G p.K257= (on ENST00000611299 / NM_001242394.1; = p.K189= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/404 reads (4%) | catalogued as rs1465832356, COSV51912807; called by muse, mutect2
- RNF217-AS1 | n.2858A>C | RNA (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
